Somatic mutation profile of tumor specimen TARGET-10-PARDRS-09A (aliquot TARGET-10-PARDRS-09A-01D) from TARGET case TARGET-10-PARDRS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.7 years (3,193 days).
Specimen TARGET-10-PARDRS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdd1f953-972d-476c-bf2d-1e4b3e8048bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDRS-10A (Blood Derived Normal), aliquot TARGET-10-PARDRS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23fe2dfb-6cf1-4b4b-9bba-f18bdb8a8dfb

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Frame Shift Ins 1, In Frame Ins 1, 5'UTR 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.692); catalogued as rs121913528, COSV55499283, COSV55796966; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 10/61 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCSER1 | c.2449G>A p.V817I | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.033); catalogued as rs1432408701, COSV61449086; called by muse, mutect2, varscan2
- DCDC1 | c.2810G>A p.R937Q (on ENST00000597505 / NM_001367979.1; = p.R44Q on NM_020869.3) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs554444976; called by muse, mutect2, varscan2
- ETV6 | c.1140G>A p.W380* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV56765951; called by muse, mutect2, varscan2
- GAS2L3 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1206951651, COSV57157345; called by muse, mutect2
- MUC4 | c.2933C>T p.P978L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as rs754419338; called by muse, mutect2, varscan2
- NEXN | c.196_197dup p.W67Nfs*25 | Frame Shift Ins (INS) | VAF 17/90 reads (19%) | catalogued as rs750492151; called by mutect2, varscan2
- OR11A1 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); catalogued as rs376507487; called by muse, mutect2, varscan2
- REELD1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.042); catalogued as rs1168124402; called by muse, mutect2
- RGS3 | c.2710G>A p.D904N (on ENST00000350696 / NM_001282923.2; = p.D623N on NM_130795.4) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs372089011; called by muse, mutect2, varscan2
- ROBO1 | c.2447G>T p.W816L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71391663; called by muse, mutect2, varscan2
- ADGRD1 | c.1367T>A p.L456Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- CDH8 | c.1085T>G p.I362S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DLST | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HNRNPU | c.1984_1992dup p.G662_G664dup (on ENST00000283179; = p.G724_G726dup on NM_004501.3) | In Frame Ins (INS) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- IVNS1ABP | c.137A>G p.H46R | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SVEP1 | c.8644G>T p.A2882S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- USP34 | c.3845T>A p.I1282N | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- ASTN1 | c.3405G>A p.R1135= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs757434000; called by muse, mutect2, varscan2
- CHL1 | c.780T>G p.L260= (on ENST00000397491 / NM_001253387.1; = p.L276= on NM_006614.4) | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- NCAM2 | c.477C>T p.S159= | Silent (SNP) | VAF 37/139 reads (27%) | catalogued as rs760416040, COSV53056239; called by muse, mutect2, varscan2
- PHF2 | c.2211T>C p.G737= | Silent (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- PRR23C | c.729G>A p.A243= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs370776270; called by muse, mutect2, varscan2
- ZNF24 | c.960G>A p.S320= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs780587593; called by muse, mutect2, varscan2
- SH3BP1 | c.*259G>A | 3'UTR (SNP) | VAF 6/14 reads (43%) | catalogued as rs763020111; called by muse, varscan2
- SLC13A1 | c.-17G>A | 5'UTR (SNP) | VAF 19/90 reads (21%) | catalogued as rs780277129; called by muse, mutect2, varscan2
